CCDI case PBCFPA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/96b54789-7a4e-44f9-a415-85ee8f7fdb4c

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Leiomyosarcoma, NOS: ICD-O-3 morphology code: 8890/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 16.0 years (5,834 days).

Biospecimens (3 samples)
- Sample 0DR3L1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DR3LU, 0DR3MA (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
